Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8HM, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8HM-01A (Primary Tumor).

PROSTATE AND PELVIC/OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 5 = 9

TERTIARY PATTERN NOT PRESENT

TUMOR LOCATION

APEX

MID

BASE

LATERAL

RIGHT

LEFT

POSTERIOR

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

NON-FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

POSTERIOR

RIGHT

SEMINAL VESICAL INVASION

PRESENT

RIGHT

SURGICAL MARGINS

FREE OF INVASIVE CARCINOMA

LYMPHOVASCULAR INVASION

PRESENT

PERINEURAL INVASION

PRESENT

TUMOR VOLUME/ size of the largest nodule

1.9x0.9x0.4cm=0.84cc

REATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

RIGHT OBTURATOR

NUMBER OF NODES IDENTIFIED: 4

NUMBER OF NODES INVOLVED BY METASTASIS: 0

LEFT OBTURATOR

NUMBER OF NODES IDENTIFIED: 5

NUMBER OF NODES INVOLVED BY METASTASIS: 0

OTHERS (SPECIFY): Left Peri-vesical

NUMBER OF NODES IDENTIFIED: 1

NUMBER OF NODES INVOLVED BY METASTASIS: 0

PATHOLOGICAL STAGING

pT3b

pN0

pMX

*COMMENT(S)

ICD O-3

Adenocarcinoma NOS 8440/3

Site: Prostate NOS C61.9

JW 11/29/13

Source: NCI Genomic Data Commons file c8f1dfed-1be7-4d8c-946e-14e62d5f6cdf (TCGA-YL-A8HM.4CDB8D1D-D1F1-4A78-A0C0-CA56CBC0689C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).